Surgical pathology report (de-identified scan), TCGA case TCGA-3A-A9IH, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site Moffitt Cancer Center, specimen TCGA-3A-A9IH-01A (Primary Tumor).

[page 1 of 4]
Pathology Report

Final Diagnosis

- A. OMENTUM, NODULE, EXCISION:
Benign mesothelial cysts.
There is no evidence of malignancy.
- B. LYMPH NODE, HEPATIC ARTERY, EXCISION:
Lymph node with reactive changes and no evidence of malignancy (0/1).
- C. PANCREAS AND SPLEEN, SUBTOTAL PANCREATECTOMY AND SPLENECTOMY:
Invasive pancreatic ductal adenocarcinoma, well to moderately differentiated.
See Key Pathological Findings.
Spleen with no significant pathologic changes and free of carcinoma.
Five regional lymph nodes with reactive changes and no evidence of malignancy (0/5).
- D. LYMPH NODE, HEPATIC ARTERY #2, EXCISION:
Lymph node with reactive changes and no evidence of malignancy (0/1).
- E. LYMPH NODE "GASTRIC NODE", EXCISION:
Lymph node with reactive changes and no evidence of malignancy (0/1).
- F. GALLBLADDER, CHOLECYSTECTOMY:
Chronic cholecystitis and cholelithiasis.
There is no evidence of malignancy.

I, _____, the attending pathologist, personally reviewed all slides and / or materials and rendered the final diagnosis. Electronically Signed Out by

Key Pathological Findings

C: Pancreas Exocrine
SPECIMEN:
Body of pancreas
Tail of pancreas
Gallbladder
Spleen
PROCEDURE:
Splenectomy
TUMOR SITE:
Pancreatic body
Pancreatic tail

ICD-O-3
Adenocarcinoma, duct NOS 8500/3
Site: ^{cyst} Pancreas body C25.1
^{path} Pancreas NOS C25.9

9/24/16/14

[page 2 of 4]
TUMOR SIZE:

Greatest dimension of solid component: 2 cm
Greatest dimension of cystic component: 0.5 cm
Additional dimensions: 2 cm

HISTOLOGIC TYPE:

Ductal adenocarcinoma

HISTOLOGIC TYPE - NON INVASIVE OTHER NEOPLASMS:

Introductal papillary mucinous neoplasm
Low grade dysplasia
Moderate dysplasia
High grade dysplasia

HISTOLOGIC GRADE:

G2: Moderately differentiated

MICROSCOPIC TUMOR EXTENSION:

Tumor is confined to pancreas

MARGINS:

Margins uninvolved by invasive carcinoma
Margins uninvolved by carcinoma in situ

TREATMENT EFFECT (applicable to carcinomas treated with neoadjuvant therapy):

No prior treatment

LYMPH-VASCULAR INVASION:

Present

PERINEURAL INVASION:

Present

PRIMARY TUMOR (pT):

pT1: Tumor limited to the pancreas, 2 cm or less in greatest dimension

REGIONAL LYMPH NODES (pN):

pN0: No regional lymph node metastasis
Number examined: 8
Number involved: 0

DISTANT METASTASIS (pM):

pM0: No Distant metastasis

ADDITIONAL PATHOLOGIC FINDINGS:

Pancreatic intraepithelial neoplasia (highest grade: PanIN PanIN 1B at the pancreatic margin)
Chronic pancreatitis
Spleen with no significant pathologic changes.

Specimen(s) Received

A OMENTUM NODULE FS
B HEPATIC ARTERY LYMPH NODE

[page 3 of 4]
C SUBTOTAL PANCREATECTOMY AND SPLENECTOMY FS
D HEPATIC ARTERY NODE #2
E GASTRIC NODE
F GALLBLADDER

Clinical History

PANCREATIC CANCER

Preoperative Diagnosis

Pancreatic cancer.

Intraoperative Consultation

FSA: OMENTUM NODULE:

Negative. Suggestive of mesothelial cysts.

FSC1-FSC2: SUBTOTAL PANCREATECTOMY AND SPLENECTOMY:

Pancreatic margin negative for carcinoma. Focal IPMN present.

Comment: This frozen section diagnosis/result was communicated to and acknowledged by Dr.

I MD, have performed the intraoperative consultations and issued the above diagnosis.

Gross Description

A. The specimen is received fresh for frozen section and labeled "omentum nodule." The specimen is received fresh and consists of 2 cysts measuring 1.0 x 1.5 cm in greatest dimension. Representative sections are submitted as FSA1. The remaining tissue is submitted for permanence as A2.

B. The specimen is labeled "hepatic artery lymph node." The specimen is received fresh and consists of 1.5 x 0.5 x 0.5 cm tan-pink, irregular lymph node which is serially sectioned and entirely submitted as B1.

C. The specimen is received fresh for frozen section analysis labeled "subtotal pancreatectomy and splenectomy, frozen section." The specimen consists of a subtotal pancreatectomy (10.0 x 4.5 x 2.0 cm), and splenectomy (13.0 x 7.5 x 1.5 cm). The pancreas is marked with green ink on the anterior aspect, orange ink on retroperitoneal surface, and blue ink on the inferior. The margin of resection is stapled. The staples are removed and the underlying tissue is submitted for frozen section as FSC1-FSC2. The pancreatic duct is probe patent and grossly appears free of tumor. An ill-defined, gray-white indurated focus is isolated in the pancreas towards the distal end of the specimen adjacent to the spleen (2.0 x 2.0 x 1.0 cm) grossly abutting the anterior margin of resection. The left is approximately 3.5 cm from staple margin of resection. The remainder of the pancreatic parenchyma is tan-yellow, lobulated, and grossly unremarkable. The capsule of adjacent spleen is red-brown and intact. Cut surface exhibits a bright red, grossly unremarkable tissue. Upon additional sectioning of the pancreatic tumor, the cut surface also reveals multiple cystic structures ranging from

[page 4 of 4]
0.1 cm to 0.5 cm in greatest dimension. Sectioning of the adjacent adipose tissue isolates no definitive lymph nodes.

A section of the tumor is submitted to Tissue Procurement Laboratory.

Permanent representative sections are submitted as:

- C3: Mirror image of tumor submitted to tissue bank
- C4-C11: Representative sections of pancreatic tumor shown in relationship to adjacent tissue
- C12: Pancreatic duct
- C13: Grossly unremarkable pancreatic parenchyma
- C14: Grossly unremarkable splenic parenchyma
- C15: Adipose tissue adjacent to pancreatic tumor

D. The specimen is labeled "hepatic artery node No. 2." The specimen is received fresh and consists of a 1.5 x 1.0 x 0.5 cm, moderately firm, tan-pink, irregular lymph node which is serially sectioned and entirely submitted as D1.

E. The specimen is labeled "gastric nodule." The specimen is received fresh and consists of a 0.5 x 0.5 x 0.2 cm, tan-pink, irregular nodule which is submitted in toto as E1.

F. The specimen is labeled "gallbladder." The specimen is received fresh and consists of a club-shaped, tan-pink, gallbladder (8.0 x 3.0 x 3.2 cm). Cystic duct is identified measuring 0.5 cm in length. Upon opening, the gallbladder contains multiple green-yellow calculi ranging from 0.2 cm to 0.8 cm in greatest dimension. The mucosal surface reveals a small polypoid lesion measuring 0.1 cm in greatest dimension. The remainder of mucosa is green-yellow, velvet-like and grossly unremarkable. The wall of the gallbladder measures up to 3 mm in thickness.

No tissue is submitted to Tissue Procurement Laboratory.

Representative sections are submitted as:

- F1: Gallbladder
- F2: Mucosal lesion

Source: NCI Genomic Data Commons file 5e0bf854-25ab-428d-89ab-79d27e86c885 (TCGA-3A-A9IH.A9D376FF-9D71-4B4F-AB05-77CD42E2EB11.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).